Somatic mutation profile of tumor specimen ALCH-B2V3-TTR1-A (aliquot ALCH-B2V3-TTR1-A-1-0-D-A85H-36) from ALCHEMIST case ALCH-B2V3, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.9 years (27,002 days).
Specimen ALCH-B2V3-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 66e1c147-8598-4e70-b900-048e448cc04b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V3-NB1-A (Blood Derived Normal), aliquot ALCH-B2V3-NB1-A-1-0-D-A78Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/648b1823-7fe5-46bb-8de4-4e91cbb4012c

The open-access MAF lists 165 somatic variants for this specimen: 109 protein-altering or splice-affecting, 32 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 96, Silent 32, Intron 12, Nonsense Mutation 8, 3'Flank 4, 3'UTR 4, Splice Site 3, 5'Flank 2, RNA 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 105/335 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 120/389 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 44/132 reads (33%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ADAR | c.2867C>T p.S956L | Missense Mutation (SNP) | VAF 83/681 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM163645; called by muse, mutect2, varscan2
- ANKRD50 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 127/273 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1476247796, COSV72385476; called by muse, mutect2, varscan2
- BPIFB6 | c.311G>A p.G104E | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62755027; called by muse, mutect2
- CDH22 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1392987280, COSV64840217; called by muse, mutect2, varscan2
- CHM | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 86/414 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV99071448; called by muse, mutect2, varscan2
- CHRNB3 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1451548832, COSV51493106; called by muse, mutect2, varscan2
- CRYZ | c.818C>T p.S273F | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.022); catalogued as COSV61717381; called by muse, mutect2, varscan2
- DLG2 | c.2171G>C p.R724T | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54670704; called by muse, mutect2, varscan2
- DMTF1 | c.2204C>T p.S735L | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99991525; called by muse, mutect2, varscan2
- DRP2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs201156733, COSV65811862; called by muse, mutect2, varscan2
- EEF2KMT | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 29/323 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as COSV69863247; called by muse, mutect2
- EML5 | c.3036C>G p.I1012M | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as COSV61351578; called by muse, mutect2
- EXT1 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 66/320 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs1231316310; called by muse, mutect2, varscan2
- F13A1 | c.131-1G>C p.X44_splice | Splice Site (SNP) | VAF 24/367 reads (7%) | catalogued as CS161520, COSV53566225; called by muse, mutect2
- FAM81A | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1359741983, COSV55676655; called by muse, mutect2
- FBXO39 | c.903C>G p.I301M | Missense Mutation (SNP) | VAF 36/243 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV58621674, COSV58622799; called by muse, mutect2, varscan2
- HARS2 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 25/245 reads (10%) | catalogued as COSV56910320; called by muse, mutect2, varscan2
- HR | c.2042G>T p.W681L | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.272); catalogued as rs772822146; called by muse, mutect2, varscan2
- IQGAP3 | c.4660C>T p.L1554F | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775975965; called by muse, varscan2
- LAMA1 | c.2590G>C p.D864H | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs750869494; called by muse, mutect2, varscan2
- LHX5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV55664638, COSV99922559; called by muse, mutect2
- MAGIX | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100891871, COSV66255661; called by muse, mutect2, varscan2
- MGAT3 | c.1502C>T p.P501L | Missense Mutation (SNP) | VAF 6/123 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1260975397; called by muse, mutect2
- MRPL22 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs756995948; called by muse, mutect2
- NLRC5 | c.3208G>A p.E1070K | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.08); catalogued as COSV99346648; called by muse, mutect2, varscan2
- NOS1 | c.3145G>A p.V1049M | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1178704994; called by muse, mutect2
- NPTXR | c.901C>A p.R301S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs755394676, COSV60729373; called by muse, mutect2, varscan2
- PCDHA6 | c.128C>A p.T43N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as rs1554131099; called by muse, mutect2
- PFAS | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs760906699; called by muse, mutect2, varscan2
- PIEZO2 | c.7002A>T p.L2334F | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767953271; called by muse, mutect2
- PRICKLE2 | c.1576G>A p.E526K (on ENST00000295902; = p.E470K on NM_198859.4) | Missense Mutation (SNP) | VAF 53/324 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.46); catalogued as COSV99896711; called by muse, mutect2, varscan2
- RND2 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.323); catalogued as rs370601120; called by muse, mutect2, varscan2
- RYBP | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as rs1286913269; called by muse, mutect2, varscan2
- RYR2 | c.5821C>T p.R1941C | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.367); catalogued as rs754811291; called by muse, mutect2, varscan2
- SHROOM1 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1285443310, COSV60581334; called by muse, mutect2, varscan2
- SLC5A1 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 31/202 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs200562349, COSV56686852, COSV56687972; called by muse, mutect2, varscan2
- SLC6A5 | c.1652C>T p.P551L | Missense Mutation (SNP) | VAF 171/455 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766837791, COSV54229114; called by muse, mutect2, varscan2
- SLFNL1 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.143); catalogued as COSV57234604; called by muse, mutect2, varscan2
- TRIM7 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs766754774; called by muse, mutect2, varscan2
- TRPC4 | c.1455C>A p.N485K | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV58996855; called by muse, mutect2, varscan2
- UBB | c.246G>C p.K82N | Missense Mutation (SNP) | VAF 42/270 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV56218466; called by muse, varscan2
- UBR5 | c.7480G>A p.D2494N | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV99640945; called by muse, mutect2, varscan2
- USP48 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV57608730; called by muse, mutect2, varscan2
- ALG1L | c.104T>C p.F35S | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- AMELX | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- ANKRD42 | c.1067A>C p.K356T | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- APOM | c.140G>C p.W47S | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCORL1 | c.827C>T p.S276F | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- BUB1 | c.1969A>G p.I657V | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C11orf65 | c.397G>C p.E133Q | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C6 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- CCNB3 | c.2640G>C p.L880F | Missense Mutation (SNP) | VAF 31/176 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CEP295 | c.6229C>T p.Q2077* | Nonsense Mutation (SNP) | VAF 48/291 reads (16%) | called by muse, mutect2, varscan2
- CHORDC1 | c.539C>G p.S180C | Missense Mutation (SNP) | VAF 61/280 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CIT | c.3950C>T p.S1317F | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNOT2 | c.1562T>A p.L521* | Nonsense Mutation (SNP) | VAF 28/524 reads (5%) | called by muse, mutect2
- COLGALT1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CPA6 | c.355G>T p.G119* | Nonsense Mutation (SNP) | VAF 44/314 reads (14%) | called by muse, mutect2, varscan2
- CPXM1 | c.1893C>A p.D631E | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CREBBP | c.7189C>G p.Q2397E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CSMD1 | c.4042G>T p.E1348* (on ENST00000520002; = p.E1347* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 59/278 reads (21%) | called by muse, mutect2, varscan2
- CTAG2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- CTNND2 | c.2072C>G p.S691* | Nonsense Mutation (SNP) | VAF 18/129 reads (14%) | called by muse, mutect2, varscan2
- ERVH48-1 | c.145C>A p.Q49K | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FAF1 | c.1436G>C p.R479T | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- FAT3 | c.5296G>T p.A1766S | Missense Mutation (SNP) | VAF 31/224 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FLG | c.4822G>C p.E1608Q | Missense Mutation (SNP) | VAF 38/464 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2
- IFT52 | c.1069G>C p.D357H | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- IMPDH1 | c.1160C>G p.S387C (on ENST00000470772 / NM_001142573.2; = p.S473C on NM_000883.4) | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ITM2A | c.276dup p.D93* | Frame Shift Ins (INS) | VAF 63/323 reads (20%) | called by mutect2, pindel, varscan2
- KCNH8 | c.2680C>G p.L894V | Missense Mutation (SNP) | VAF 37/211 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- KCNN3 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 30/520 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KIR3DL3 | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- KLK14 | c.45G>T p.M15I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- KNDC1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- LMBRD2 | c.1640+1G>A p.X547_splice | Splice Site (SNP) | VAF 24/298 reads (8%) | called by muse, mutect2
- MBTPS2 | c.617C>T p.T206I | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- MTFMT | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.141); called by muse, varscan2
- NAGS | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NOM1 | c.2292C>G p.I764M | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2
- NUP155 | c.756G>C p.R252S (on ENST00000231498 / NM_153485.3; = p.R193S on NM_004298.4) | Missense Mutation (SNP) | VAF 30/343 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2
- OR5M8 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 30/340 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.394); called by muse, mutect2
- PAF1 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 44/254 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDHA2 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 28/309 reads (9%) | called by muse, mutect2
- PLEKHH1 | c.3430G>C p.E1144Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.403); called by muse, mutect2
- PRRC2A | c.1333G>C p.E445Q | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- R3HDM1 | c.1267C>A p.H423N | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RELN | c.6505C>G p.L2169V | Missense Mutation (SNP) | VAF 58/406 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2
- SDCCAG8 | c.50A>T p.Y17F | Missense Mutation (SNP) | VAF 45/329 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC6A11 | c.947G>T p.C316F | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SMARCC2 | c.2638G>C p.E880Q | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- STK40 | c.133C>G p.P45A | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYCP2 | c.4028C>G p.S1343C | Missense Mutation (SNP) | VAF 32/415 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.025); called by muse, mutect2
- TPP2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 34/219 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TRIM66 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TRIP11 | c.4461G>A p.M1487I | Missense Mutation (SNP) | VAF 53/448 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- TRRAP | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TSEN54 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC21B | c.2139-1G>C p.X713_splice | Splice Site (SNP) | VAF 66/260 reads (25%) | called by muse, varscan2
- UBOX5 | c.1603G>C p.D535H | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- UBTFL1 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- WDR43 | c.1387C>T p.P463S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ZFHX4 | c.8196C>A p.Y2732* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | called by muse, mutect2, varscan2
- ZFYVE9 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- ZNF518A | c.2962G>C p.E988Q | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZNF765 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 45/292 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ACVRL1 | c.1362G>T p.R454= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- ATP11C | c.2532A>T p.A844= | Silent (SNP) | VAF 30/125 reads (24%) | called by muse, mutect2, varscan2
- BBOX1 | c.435G>A p.K145= | Silent (SNP) | VAF 65/358 reads (18%) | catalogued as COSV54189699; called by muse, mutect2, varscan2
- BTN3A3 | c.564G>C p.P188= | Silent (SNP) | VAF 33/434 reads (8%) | called by muse, mutect2
- CCDC60 | c.219G>A p.L73= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV100554678, COSV59540716; called by muse, mutect2, varscan2
- CUL9 | c.5601G>A p.Q1867= | Silent (SNP) | VAF 34/294 reads (12%) | called by muse, mutect2, varscan2
- DRC1 | c.1596C>T p.F532= | Silent (SNP) | VAF 27/86 reads (31%) | called by muse, mutect2, varscan2
- H1-5 | c.426C>G p.A142= | Silent (SNP) | VAF 29/203 reads (14%) | called by muse, mutect2, varscan2
- KIF13B | c.2910C>T p.I970= | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1381618918, COSV72954595; called by muse, mutect2, varscan2
- KIF21B | c.2466G>T p.L822= | Silent (SNP) | VAF 16/74 reads (22%) | catalogued as COSV59762373; called by muse, mutect2
- MAP1B | c.3984T>A p.T1328= | Silent (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- MIER3 | c.882C>G p.L294= (on ENST00000381199 / NM_001297599.2; = p.L293= on NM_152622.4) | Silent (SNP) | VAF 34/318 reads (11%) | catalogued as COSV101167442; called by muse, mutect2, varscan2
- MLNR | c.768C>T p.F256= | Silent (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- MORC2 | c.1308C>T p.Y436= (on ENST00000397641 / NM_001303256.3; = p.Y374= on NM_014941.3) | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as rs768240412; ClinVar: likely benign; called by muse, mutect2, varscan2
- NR1H2 | c.996C>T p.F332= | Silent (SNP) | VAF 50/178 reads (28%) | called by muse, mutect2, varscan2
- NUP133 | c.2196C>T p.L732= | Silent (SNP) | VAF 12/146 reads (8%) | called by muse, mutect2
- POGZ | c.1971C>T p.L657= | Silent (SNP) | VAF 30/556 reads (5%) | catalogued as rs548178282, COSV55035897; called by muse, mutect2
- PRKDC | c.2272C>T p.L758= | Silent (SNP) | VAF 47/223 reads (21%) | called by muse, mutect2, varscan2
- ROBO2 | c.1596T>C p.D532= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, mutect2, varscan2
- SCUBE1 | c.2826G>A p.L942= | Silent (SNP) | VAF 14/92 reads (15%) | called by muse, mutect2, varscan2
- SLC4A8 | c.2349G>A p.V783= | Silent (SNP) | VAF 28/276 reads (10%) | called by muse, mutect2
- SLC4A8 | c.2664G>A p.L888= | Silent (SNP) | VAF 21/155 reads (14%) | called by muse, mutect2, varscan2
- SLC6A2 | c.126C>G p.V42= | Silent (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- SMG5 | c.2406G>A p.E802= | Silent (SNP) | VAF 15/182 reads (8%) | called by muse, mutect2
- SNAI3 | c.471C>T p.C157= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- TACC2 | c.6060C>T p.F2020= (on ENST00000334433; = p.F98= on NM_006997.4) | Silent (SNP) | VAF 38/173 reads (22%) | catalogued as rs1389808854; called by muse, mutect2, varscan2
- TMEM63A | c.615C>T p.F205= | Silent (SNP) | VAF 26/204 reads (13%) | called by muse, mutect2, varscan2
- TRMT13 | c.1077G>A p.V359= | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as rs767890777; called by muse, mutect2, varscan2
- UTP20 | c.7002G>A p.T2334= | Silent (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- ZNF524 | c.603C>T p.P201= | Silent (SNP) | VAF 20/127 reads (16%) | catalogued as COSV99684570; called by muse, mutect2, varscan2
- ZNF606 | c.2226A>G p.E742= | Silent (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- ZNF780A | c.825A>G p.K275= | Silent (SNP) | VAF 148/292 reads (51%) | called by muse, mutect2, varscan2
- ACACA | c.*23G>T | 3'UTR (SNP) | VAF 34/198 reads (17%) | catalogued as rs748601714; called by muse, mutect2, varscan2
- ADAD2 | c.*47G>A | 3'UTR (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- AL353804.6 | chrX:73827862 G>C | 3'Flank (SNP) | VAF 91/467 reads (19%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1363+39G>C | Intron (SNP) | VAF 36/249 reads (14%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93732068 C>G | 3'Flank (SNP) | VAF 34/208 reads (16%) | called by muse, mutect2, varscan2
- COL18A1 | c.3754-164C>G | Intron (SNP) | VAF 36/178 reads (20%) | called by muse, mutect2, varscan2
- DCTN5 | c.452-34C>G | Intron (SNP) | VAF 19/78 reads (24%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-2356C>T | Intron (SNP) | VAF 3/14 reads (21%) | catalogued as rs1352073909; called by muse, mutect2
- FHOD3 | c.1445+5604G>A | Intron (SNP) | VAF 12/154 reads (8%) | catalogued as COSV57163905; called by muse, mutect2
- GBGT1 | chr9:133149001 C>T | 3'Flank (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- GSTP1 | chr11:67583801 G>A | 5'Flank (SNP) | VAF 17/86 reads (20%) | called by muse, mutect2, varscan2
- IMPA2 | c.231-1529_231-1485del | Intron (DEL) | VAF 19/225 reads (8%) | called by mutect2, pindel
- KRT8P11 | n.509C>T | RNA (SNP) | VAF 36/150 reads (24%) | catalogued as rs775922802; called by muse, mutect2, varscan2
- MAGEA5 | n.177A>G | RNA (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+976G>T | Intron (SNP) | VAF 40/106 reads (38%) | catalogued as rs979500953; called by muse, mutect2, varscan2
- MDM4 | c.343+570G>A | Intron (SNP) | VAF 15/218 reads (7%) | called by muse, mutect2
- NPIPA5 | c.642+221G>C | Intron (SNP) | VAF 34/396 reads (9%) | called by muse, mutect2
- OR52A4P | chr11:5120728 G>C | 3'Flank (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- PHETA1 | c.*724C>T | 3'UTR (SNP) | VAF 14/126 reads (11%) | called by muse, mutect2, varscan2
- PLXDC1 | c.*4319C>T | 3'UTR (SNP) | VAF 28/157 reads (18%) | catalogued as rs781073291; called by muse, mutect2, varscan2
- SEPTIN3 | c.1012-9C>T | Intron (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- SERP1 | chr3:150546771 C>G | 5'Flank (SNP) | VAF 33/161 reads (20%) | catalogued as rs545149907; called by muse, mutect2, varscan2
- THRB | c.284-12603G>A | Intron (SNP) | VAF 24/155 reads (15%) | called by muse, mutect2, varscan2
- ZMYND8 | c.26-8700C>T | Intron (SNP) | VAF 12/153 reads (8%) | called by muse, mutect2
